Somatic mutation profile of tumor specimen 0DHPKE from CCDI case PBBTYI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.9 years (317 days).
Specimen 0DHPKE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9190e76e-f3f2-42bb-b52c-c4acc59cc3d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHPJ7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18c47f5c-462d-4d6c-a7ed-ea32e05c9c3f

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF11 | c.458+25C>T | Intron (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2, varscan2
